Somatic mutation profile of tumor specimen TCGA-W5-AA2G-01A (aliquot TCGA-W5-AA2G-01A-11D-A417-09) from TCGA case TCGA-W5-AA2G, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 62.8 years (22,933 days).
Specimen TCGA-W5-AA2G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a953d8d-9f5a-477f-b51f-ca25cda8790a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA2G-10A (Blood Derived Normal), aliquot TCGA-W5-AA2G-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7b9b88e-aeb3-4a98-892d-cd55d50dba70

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 25, Silent 11, Nonsense Mutation 4, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CALD1 | c.1597G>A p.G533S (on ENST00000361675 / NM_033138.4; = p.G278S on NM_004342.7) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs768053736; called by muse, mutect2
- CD96 | c.55G>T p.V19F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99343023; called by muse, mutect2
- COL9A1 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs780405287; called by muse, mutect2, varscan2
- FBN2 | c.7660T>G p.F2554V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs775848753, COSV52491221; ClinVar: likely benign; called by muse, mutect2, varscan2
- NR2C1 | c.1699G>T p.E567* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV60690186; called by muse, mutect2, varscan2
- OR10H4 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs749272961, COSV59061323; called by muse, mutect2, varscan2
- PHF20L1 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as rs1339661079; called by muse, mutect2, varscan2
- RYR3 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs745418555, COSV66781899; called by muse, mutect2, varscan2
- SPTA1 | c.5432G>A p.R1811Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748672916, COSV63752118; called by muse, mutect2, varscan2
- TUFT1 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1558017897; called by muse, mutect2, varscan2
- ALDH3A1 | c.572G>C p.G191A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID5A | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CNTN2 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- COL7A1 | c.7141C>G p.P2381A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CTCF | c.963_964dup p.H322Lfs*12 | Frame Shift Ins (INS) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- EFCAB6 | c.3011A>G p.E1004G | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- EPHA2 | c.1402A>T p.K468* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- GHDC | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- GSDMA | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HTR5A | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IQCN | c.1948C>A p.P650T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRP2 | c.3012G>T p.M1004I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MAGEE1 | c.2557A>T p.R853W | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MLXIPL | c.338dup p.L114Afs*40 | Frame Shift Ins (INS) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- NBEAL1 | c.5542del p.E1848Kfs*2 | Frame Shift Del (DEL) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- PRRC2C | c.6430C>A p.P2144T (on ENST00000367742; = p.P2142T on NM_015172.4) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- REV3L | c.8396A>C p.K2799T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- RUVBL2 | c.1351C>A p.L451I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2
- UBTF | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR55 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZMYM4 | c.487A>C p.K163Q | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP11C | c.294T>C p.L98= | Silent (SNP) | VAF 6/191 reads (3%) | catalogued as rs941292053; called by muse, mutect2
- CACNG2 | c.18A>C p.R6= | Silent (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- CUBN | c.570T>C p.C190= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- DLGAP3 | c.453G>C p.G151= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- F9 | c.822A>G p.K274= | Silent (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- KCNK4 | c.21G>A p.L7= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as COSV57403714; called by muse, mutect2
- PHKA2 | c.2655C>T p.I885= | Silent (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- PKP1 | c.993C>T p.I331= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs1452047151; called by mutect2, varscan2
- RYR2 | c.5190G>A p.T1730= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs397516541; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TSSC4 | c.150C>T p.S50= | Silent (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- ZNF18 | c.63C>T p.S21= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100503044; called by muse, mutect2, varscan2
